Surgical pathology report (de-identified scan), TCGA case TCGA-GS-A9U3, project TCGA-DLBC (Lymphoid Neoplasm Diffuse Large B-cell Lymphoma), tissue source site Fundacio Clinic per a la Recerca Biomedica, specimen TCGA-GS-A9U3-01A (Primary Tumor).

ICD-O-3
Lymphoma, diffuse large B-cell NOS
9680/3
Site: Lymph node, inguinal
C77.4
12/31/14

LEFT INGUINAL LYMPH NODE:

We receive a lymph node measuring 3,5 x 3,5 x 2,8 cm.

INGUINAL LYMPH NODE (BIOPSY):

- DIFFUSE LARGE B-CELL LYMPHOMA, CD20 POSITIVE

The lymph node shows a diffuse and partially nodular lymphoid infiltration composed by large centroblastic cells, accompanied by abundant small lymphocytes, histiocytes and plasma cells.

The atypical cells are positive for CD20, BCL2, BCL6 and IgD, and are negative for CD10 and MUM1. There is Kappa light chain restriction. The small accompanying lymphocytes are CD3positive. The Ki-67 proliferative index is 50-60%.

PCR BCL2 : Rearranged

Source: NCI Genomic Data Commons file c4c567e5-139e-4848-93be-f020e5db2a59 (TCGA-GS-A9U3.B4BF1DF0-5250-49DB-86C9-1C17AE27D51E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).